FM case AD103 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/3468b376-b05e-40e7-851b-25bb9251378f

Male, 30.6 years: Adenocarcinoma, NOS (ICD-O-3 8140/3). Sample type: Tumor.
